CCDI case PBCMDS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/cb559741-717f-4f95-a48f-226789232683

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, metastatic: ICD-O-3 morphology code: 8000/6; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.3 years (4,480 days).

Biospecimens (3 samples)
- Samples 0DVCDT, 0DVCFH (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCFS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
